TCGA case TCGA-97-8174 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Washington University - NYU. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8c695c24-e7f9-449a-9258-a1bc8a33bf9a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 67 years; Vital status: Dead; Days to death: 164 days.

Diagnoses (1)
1. Papillary adenocarcinoma, NOS: ICD-O-3 morphology code: 8260/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 67.7 years (24,725 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T2b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Vinorelbine; Days to treatment start: 53 days; Days to treatment end: 102 days.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- ECOG performance status: 0; Timepoint: Preoperative.
- Follow-up contact recording only the day: day 164.

Molecular and laboratory tests
- KRAS mutation, nos: Negative.

Other clinical attributes
- DLCO (% of predicted): 90; FEV1/FVC after bronchodilator (%): 86; FEV1/FVC before bronchodilator (%): 81; FEV1 after bronchodilator (% of reference): 99; FEV1 before bronchodilator (% of reference): 91.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 40; Tobacco smoking onset year: 1965; Tobacco smoking quit year: 1985.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-97-8174-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 1.5; Shortest dimension: 0.5.
  Slide TCGA-97-8174-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 0.
- Sample TCGA-97-8174-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Papillary Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tobacco smoking history indicator: 3; Anatomic organ subdivision: R-Upper; KRAS mutation found: No; KRAS gene analysis indicator: Yes; EGFR mutation status: Yes; Eml4 alk translocation status: Yes; Eml4 alk analysis type: Fish; Pulmonary function test indicator: Yes; New tumor event diagnosis indicator: No.
- Drug treatment 2: Pharmaceutical therapy drug name: CISplatinum.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 164 days; disease-specific survival: event status not recorded, 164 days; progression-free interval: no event (censored), 164 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-97-8174-01A-11D-2283-01): tumor purity 0.3, ploidy 3.62, whole-genome doublings 1.
